CCDI case PBCPZG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/b3b14c4b-a333-4643-8855-eda50e27bc29

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 3.9 years (1,425 days).

Biospecimens (2 samples)
- Sample 0DX7EV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX7FT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
